MMRF case MMRF_1500 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/ba2be3d7-4305-4dc3-a912-cf85440492e0

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 60 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 60.4 years (22,054 days); ISS stage: I; Days to last known disease status: 1,264 days (3.5 years); Days to last follow up: 1,264 days (3.5 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 65 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 46 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 102 days; Days to treatment end: 102 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 122 days; Days to treatment end: 122 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 123 days; Days to treatment end: 123 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 260 days; Days to treatment end: 263 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 262 days; Days to treatment end: 262 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 264 days; Days to treatment end: 264 days.
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 947 days (2.6 years); Days to treatment end: 1,198 days (3.3 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 947 days (2.6 years); Days to treatment end: 974 days (2.7 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,214 days (3.3 years); Days to treatment end: 1,214 days (3.3 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,215 days (3.3 years); Days to treatment end: 1,215 days (3.3 years).
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,243 days (3.4 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -18 (ECOG 1): M Protein 0.29 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 25.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.313 mg/dL; Immunoglobulin G 7.44 g/L; Immunoglobulin A 0.59 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 2.13 µg/mL; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 374 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Albumin 44 g/L; Total Protein 6.5 g/dL; Glucose 7.59 mmol/L.
- Day 79 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.857 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.68 mg/dL; Immunoglobulin G 5.99 g/L; Immunoglobulin A 0.35 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 3.15 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 340 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.3 mmol/L; Albumin 45 g/L; Total Protein 6.4 g/dL; Glucose 4.95 mmol/L.
- Day 170 (ECOG 1): M Protein 0.17 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.35 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.73 mg/dL; Immunoglobulin G 6.52 g/L; Immunoglobulin A 0.46 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 2.09 µg/mL; Lactate Dehydrogenase 3.72 µkat/L; Hemoglobin 7.19 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.18 mmol/L; Albumin 39 g/L; Total Protein 5.8 g/dL; Glucose 9.68 mmol/L.
- Day 275 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.102 mg/dL; Immunoglobulin G 18.7 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 1.36 µg/mL; Hemoglobin 7.5 mmol/L; Leukocytes 2.3 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 24 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2 mmol/L; Albumin 32 g/L; Total Protein 5.7 g/dL; Glucose 5.39 mmol/L.
- Day 340 (ECOG 1): M Protein 0.17 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.465 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.496 mg/dL; Immunoglobulin G 6.4 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.32 g/L; Lactate Dehydrogenase 3.43 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 117 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.25 mmol/L; Albumin 43 g/L; Total Protein 6.6 g/dL; Glucose 7.98 mmol/L.
- Day 463 (ECOG 0): M Protein 0.17 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.885 mg/dL; Immunoglobulin G 8.22 g/L; Immunoglobulin A 0.84 g/L; Immunoglobulin M 0.63 g/L; Beta 2 Microglobulin 1.6 µg/mL; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 8.6 ×10⁹/L; Absolute Neutrophil 5.8 ×10⁹/L; Platelets 229 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 6.6 g/dL; Glucose 6.93 mmol/L.
- Day 526 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.996 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.615 mg/dL; Immunoglobulin G 8.89 g/L; Immunoglobulin A 0.87 g/L; Immunoglobulin M 0.68 g/L; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Albumin 45 g/L; Total Protein 7.1 g/dL; Glucose 5.89 mmol/L.
- Day 617 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.917 mg/dL; Immunoglobulin G 8.94 g/L; Immunoglobulin A 0.85 g/L; Immunoglobulin M 0.45 g/L; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 45 g/L; Total Protein 6.3 g/dL; Glucose 6.49 mmol/L.
- Day 708 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.498 mg/dL; Immunoglobulin G 7.92 g/L; Immunoglobulin A 0.73 g/L; Immunoglobulin M 0.54 g/L; Beta 2 Microglobulin 1.7 µg/mL; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Albumin 44 g/L; Total Protein 6.5 g/dL; Glucose 6.16 mmol/L.
- Day 806 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.645 mg/dL; Immunoglobulin G 7.42 g/L; Immunoglobulin A 0.74 g/L; Immunoglobulin M 0.61 g/L; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 9.5 ×10⁹/L; Absolute Neutrophil 5.9 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.33 mmol/L; Albumin 45 g/L; Total Protein 6.3 g/dL; Glucose 6.66 mmol/L.
- Day 912 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.779 mg/dL; Immunoglobulin G 7.14 g/L; Immunoglobulin A 0.79 g/L; Immunoglobulin M 0.61 g/L; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 9.05 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.28 mmol/L; Albumin 50 g/L; Total Protein 7 g/dL; Glucose 7.65 mmol/L.
- Day 967 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.799 mg/dL; Immunoglobulin G 5.59 g/L; Immunoglobulin A 0.57 g/L; Immunoglobulin M 0.55 g/L; Lactate Dehydrogenase 3.22 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.15 mmol/L; Albumin 39 g/L; Total Protein 5.6 g/dL; Glucose 6.27 mmol/L.
- Day 1,074 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.627 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.198 mg/dL; Immunoglobulin G 3.77 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 4.5 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 14.8 ×10⁹/L; Absolute Neutrophil 13 ×10⁹/L; Platelets 66 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 5.8 g/dL; Glucose 10.8 mmol/L.
- Day 1,170 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.137 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.1 mg/dL; Immunoglobulin G 2.37 g/L; Immunoglobulin A 0.09 g/L; Immunoglobulin M 0.06 g/L; Lactate Dehydrogenase 5.47 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 5.4 g/dL; Glucose 5.67 mmol/L.
- Day 1,264 (ECOG 2): M Protein 0.34 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.734 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 1.73 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 1.81 µg/mL; Lactate Dehydrogenase 10.1 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 62 ×10⁹/L; Creatinine 84 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.38 mmol/L; Albumin 41 g/L; Total Protein 7 g/dL; Glucose 8.09 mmol/L.

Other clinical attributes
- Day -18: Weight: 81 kg; Height: 172 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling.
- Relative with cancer history: yes; Relationship type: Maternal Grandfather; Relationship primary diagnosis: Multiple Myeloma; Relationship sex at birth: male.

Biospecimens (3 samples)
- Sample MMRF_1500_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -18 days.
- Sample MMRF_1500_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 912 days (2.5 years).
- Sample MMRF_1500_2_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 912 days (2.5 years).
